Somatic mutation profile of tumor specimen TARGET-10-PARTEF-09A (aliquot TARGET-10-PARTEF-09A-01D) from TARGET case TARGET-10-PARTEF, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.1 years (1,123 days).
Specimen TARGET-10-PARTEF-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c34f26b6-8317-4aef-8156-1081cfdc6f5a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARTEF-10A (Blood Derived Normal), aliquot TARGET-10-PARTEF-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fb521089-c12b-4161-9047-df08db377914

The open-access MAF lists 11 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, Nonsense Mutation 1, Splice Region 1, 3'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CBY2 | c.647C>T p.S216L | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.463); catalogued as COSV60118520; called by muse, mutect2, varscan2
- IFT43 | c.213G>A p.S71= | Splice Region (SNP) | VAF 32/85 reads (38%) | catalogued as rs1172328141, COSV53137890; called by muse, mutect2, varscan2
- POLE | c.2462G>A p.R821H | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757051826; called by muse, mutect2, varscan2
- RIMS2 | c.3311G>A p.R1104Q (on ENST00000666250 / NM_001348490.2; = p.R912Q on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057518581, COSV99211923; called by muse, mutect2, varscan2
- CEACAM16 | c.1036C>A p.L346M | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM162B | c.237G>A p.W79* | Nonsense Mutation (SNP) | VAF 72/167 reads (43%) | called by muse, mutect2, varscan2
- NDFIP2 | c.214G>C p.G72R | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PIM3 | c.952dup p.S318Kfs*15 | Frame Shift Ins (INS) | VAF 10/31 reads (32%) | called by mutect2, pindel, varscan2
- AHNAK | c.14487C>T p.D4829= | Silent (SNP) | VAF 63/145 reads (43%) | catalogued as rs141073062; called by muse, mutect2, varscan2
- SCIN | c.1446A>G p.L482= (on ENST00000297029 / NM_001112706.3; = p.L235= on NM_033128.3) | Silent (SNP) | VAF 40/88 reads (45%) | catalogued as rs1175739223; called by muse, mutect2, varscan2
- GPR42 | c.*96T>A | 3'UTR (SNP) | VAF 7/36 reads (19%) | called by muse, mutect2, varscan2
